Surgical pathology report (de-identified scan), TCGA case TCGA-A6-2685, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-A6-2685-01A (Primary Tumor).

SPECIMEN

Left colon

CLINICAL NOTES

PRE-OP DIAGNOSIS: Sigmoid colon cancer

GROSS DESCRIPTION

The specimen is received unfixed labeled "left colon" and consists of a colectomy specimen measuring 30 cm in length and 3 cm in diameter. There is abundant pericolic fat. The entire specimen is 7 cm in diameter. The colon is opened with a single incision on the antimesenteric surface. There is a pink neoplasm originating on the mucosal surface measuring 3.5 x 2.5 x 0.7 cm that is 9 cm from one margin of resection. A portion of the specimen is taken for research purposes. Sections after clearing and fixation.

BLOCK SUMMARY: 1,2 - Margins of resection; 3-6 - tumor; 7-17 - lymph nodes.

MICROSCOPIC DESCRIPTION

Tumor type: Colonic adenocarcinoma.
Tumor grade: 2 out of 3
Tumor size: 3.5 cm.
Distance to nearest margin: 9 cm.
Level of penetration: Carcinoma penetrates through the muscularis propria into pericolic soft tissue.
Margins of resection: Negative for malignancy.
Vascular invasion: Absent.
Host response: Mild acute and chronic inflammation.
Attached lymph nodes: There is no evidence of malignancy in any of twenty-nine pericolic lymph nodes.

Non-lymph node pericolic tumor: Absent.

MICROSCOPIC DESCRIPTION

pTNM Stage: T3 N0.
Other findings: None.
5 3260F 153.3

DIAGNOSIS

Colon, left, resection: Moderately differentiated colonic adenocarcinoma.

Note: Carcinoma invades through the muscularis propria into pericolic soft tissue. There is no evidence of malignancy in any of twenty-nine pericolic lymph nodes.

Source: NCI Genomic Data Commons file fd4bbe20-0b0b-4729-bb8f-0333b1b9cb70 (TCGA-A6-2685.4D01D457-E681-48C9-AC38-323C582105C3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).